Somatic mutation profile of tumor specimen TARGET-10-PAUBTC-09A (aliquot TARGET-10-PAUBTC-09A-01D) from TARGET case TARGET-10-PAUBTC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (667 days).
Specimen TARGET-10-PAUBTC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0d2c1e7-da3a-46ba-b6e5-ef1e5699a0b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAUBTC-10A (Blood Derived Normal), aliquot TARGET-10-PAUBTC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/665cf043-260f-4e1e-941a-505203e89c5b

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 2, Splice Site 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OTOF | c.5712+1G>A p.X1904_splice (on ENST00000272371 / NM_194248.3; = p.X1137_splice on NM_004802.4) | Splice Site (SNP) | VAF 38/64 reads (59%) | catalogued as rs80356604, COSV55506006; ClinVar: pathogenic; called by muse, varscan2
- JAK2 | c.2772T>A p.N924K | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); catalogued as COSV67619451; called by muse, varscan2
- LCT | c.3986C>T p.T1329M | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs555708380, COSV51543584, COSV51545051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH1 | c.4793G>C p.R1598P | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.918); catalogued as COSV53027279, COSV53097635; called by muse, mutect2, varscan2
- OR5C1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV65455828; called by mutect2, varscan2
- PDCD10 | c.557+8C>T | Splice Region (SNP) | VAF 30/50 reads (60%) | catalogued as COSV67102528; called by muse, mutect2, varscan2
- WDR97 | c.878C>A p.T293N | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as rs993881873; called by muse, mutect2
- CNTRL | c.2009C>A p.A670E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- LIMS2 | c.172-47G>T | Intron (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- OR10D1P | n.186C>A | RNA (SNP) | VAF 12/153 reads (8%) | called by muse, mutect2
- USP42 | c.442+1363C>A | Intron (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
